Gene-level copy-number profile of tumor specimen TCGA-HT-7879-01A from TCGA case TCGA-HT-7879, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 31.8 years (11,622 days).
Specimen TCGA-HT-7879-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.73c466ac-d50c-46b2-a20b-eb10623d2ae5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HT-7879-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0bd14422-f839-4acf-b177-73c7e068fe11

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,060; copy number 2: 53,413; copy number 3: 1,029; copy number 4: 66; copy number 5: 252.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HT-7879-01A-11D-2391-01): tumor purity 0.68, ploidy 3.97, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 252 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:18,738,119–32,396,147, 251 genes, copy number 5 (broad region; genes not listed).
- chr12:32,477,382–32,477,471, 1 gene, copy number 5: RNU6-494P.

Autosomal genes at a single copy (total copy number 1): 2,679. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
